Gene-level copy-number profile of tumor specimen TARGET-40-PALECC-01A from TARGET case TARGET-40-PALECC, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 10.0 years (3,661 days).
Specimen TARGET-40-PALECC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.a80e2747-dd2a-50a4-a838-654352471e48.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALECC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate.
https://portal.gdc.cancer.gov/files/da69c7d1-d4c9-463f-a18c-7def3d286e1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 530; copy number 1: 14,239; copy number 2: 39,570; copy number 3: 5,057; copy number 4: 225; copy number 5: 65; copy number 6: 9; copy number 7: 161; copy number 8: 12; copy number 10: 6; copy number 12: 184; copy number 17: 114; copy number 18: 1; copy number 20: 4; copy number 43: 54; copy number 46: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr18:47,501,172–47,558,383, 2 genes (within-gene range 0–2): AC102797.2, AC102797.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 612 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,471,119–237,471,191, 1 gene, copy number 5: MIR4428.
- chr6:37,257,772–49,078,051, 256 genes, copy number 5–20 (within-gene range 1–20) (broad region; genes not listed).
- chr6:54,602,487–54,945,099, 7 genes, copy number 8: RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1.
- chr8:86,016,819–86,043,507, 2 genes, copy number 5: AC023194.1, AC023194.2.
- chr10:53,766,400–53,766,614, 1 gene, copy number 18: AL365496.1.
- chr10:60,778,331–61,026,420, 4 genes, copy number 8: CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr10:61,781,745–62,480,288, 7 genes, copy number 6: LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365.
- chr11:45,387,215–45,665,622, 8 genes, copy number 7 (within-gene range 1–7): AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1.
- chr11:101,890,674–104,682,581, 56 genes, copy number 43–46: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1.
- chr14:22,630,929–22,644,352, 1 gene, copy number 8 (within-gene range 2–8): OR6J1.
- chr17:17,476,994–22,606,703, 269 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
